Gene-level copy-number profile of tumor specimen C3N-03767-01 from CPTAC case C3N-03767, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.1 years (24,142 days).
Specimen C3N-03767-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3d7880c-dda5-4313-a065-1b14d478e7f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03767-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/81e82978-8282-4796-8989-8f0b475190b1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 5; copy number 2: 900; copy number 3: 6,110; copy number 4: 14,701; copy number 5: 12,275; copy number 6: 9,824; copy number 7: 6,378; copy number 8: 3,861; copy number 9: 1,495; copy number 10: 1,782; copy number 11: 407; copy number 12: 133; copy number 14: 65; copy number 15: 248; copy number 20: 121.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:27,829,276–27,944,497, 2 genes: AL360014.1, AL353746.1.
- chr9:42,183,659–42,354,454, 5 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr16:11,555–14,090, 1 gene: DDX11L10.
- chr16:34,941,977–35,912,516, 80 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,250 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,589,494–91,621,421, 1 gene, copy number 9 (within-gene range 6–9): AC116050.1.
- chr2:116,687,218–128,067,901, 138 genes, copy number 10 (broad region; genes not listed).
- chr2:192,749,845–193,277,614, 5 genes, copy number 10: PCGEM1, RPS17P8, AC013401.2, SLC44A3P1, DNAJC17P1.
- chr4:143,286,293–160,818,869, 277 genes, copy number 11 (broad region; genes not listed).
- chr8:39,860,219–144,291,438, 1,536 genes, copy number 9–11 (broad region; genes not listed).
- chr12:31,382,226–31,591,136, 1 gene, copy number 10 (within-gene range 8–10): DENND5B.
- chr12:31,506,303–31,729,121, 10 genes, copy number 10 (within-gene range 8–10): Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1.
- chr12:33,374,238–34,249,958, 18 genes, copy number 10: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:16,499,533–16,664,135, 2 genes, copy number 11: AC136431.1, AC136619.2.
- chr16:18,570,448–18,598,328, 2 genes, copy number 11: AC136618.1, ABCC6P1.
- chr17:18,781,111–21,641,536, 164 genes, copy number 10 (broad region; genes not listed).
- chr17:36,861,674–41,624,842, 239 genes, copy number 15 (broad region; genes not listed).
- chr17:43,338,741–44,650,349, 68 genes, copy number 14–15 (broad region; genes not listed).
- chr17:46,243,606–46,757,464, 13 genes, copy number 9 (within-gene range 8–9): MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF.
- chr17:57,253,236–73,092,712, 413 genes, copy number 10–20 (broad region; genes not listed).
- chr21:10,482,738–13,016,692, 7 genes, copy number 10–15 (within-gene range 6–15): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
